Somatic mutation profile of tumor specimen TARGET-30-PASAAN-01A (aliquot TARGET-30-PASAAN-01A-01D) from TARGET case TARGET-30-PASAAN, project TARGET-NBL (Neuroblastoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neuroblastoma, NOS; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 4.2 years (1,525 days).
Specimen TARGET-30-PASAAN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3085781b-1ddc-406a-b882-49643614beeb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PASAAN-10A (Blood Derived Normal), aliquot TARGET-30-PASAAN-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/38b56263-a0d4-4b05-b505-0eba01c8970e

The open-access MAF lists 18 somatic variants for this specimen: 12 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 9, Silent 6, Nonsense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PTPN11 | c.1381G>A p.A461T | Missense Mutation (SNP) | VAF 18/96 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs121918468, CM043335, CM096577, COSV100692090, COSV61005148; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BAG3 | c.1124C>T p.P375L | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as COSV64841817; called by muse, mutect2, varscan2
- CHL1 | c.2050T>G p.F684V (on ENST00000397491 / NM_001253387.1; = p.F700V on NM_006614.4) | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56589515; called by muse, mutect2, varscan2
- CLBA1 | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.095); catalogued as COSV66347915; called by muse, mutect2, varscan2
- COG1 | c.1462G>A p.A488T | Missense Mutation (SNP) | VAF 31/253 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.59); catalogued as COSV55428909; called by muse, mutect2, varscan2
- KDM5B | c.529C>T p.R177* | Nonsense Mutation (SNP) | VAF 8/69 reads (12%) | catalogued as rs756616242, COSV52505933; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TMCO4 | c.53C>A p.A18D | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.02); catalogued as COSV53871171; called by muse, mutect2, varscan2
- TNFAIP1 | c.489C>A p.N163K | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV56876082; called by muse, mutect2, varscan2
- ZDBF2 | c.5035C>T p.R1679* | Nonsense Mutation (SNP) | VAF 14/65 reads (22%) | catalogued as rs559177241, COSV65623385; called by muse, mutect2, varscan2
- FAM209B | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 9/88 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- PARM1 | c.599C>T p.S200F | Missense Mutation (SNP) | VAF 11/134 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.101); called by muse, mutect2
- ZNF91 | c.323T>A p.L108* | Nonsense Mutation (SNP) | VAF 5/59 reads (8%) | called by muse, mutect2
- AHNAK2 | c.13173A>G p.V4391= | Silent (SNP) | VAF 12/168 reads (7%) | catalogued as rs1463283730; called by muse, mutect2
- CD300A | c.483C>A p.A161= | Silent (SNP) | VAF 21/133 reads (16%) | catalogued as COSV60409768; called by muse, mutect2, varscan2
- EBPL | c.435C>T p.T145= | Silent (SNP) | VAF 10/83 reads (12%) | catalogued as COSV54431873, COSV54433504; called by muse, mutect2, varscan2
- EMD | c.654C>T p.G218= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV63962083; called by muse, mutect2
- TBCD | c.1065A>T p.P355= | Silent (SNP) | VAF 7/87 reads (8%) | called by muse, mutect2
- TNFAIP8 | c.132C>T p.D44= | Silent (SNP) | VAF 5/12 reads (42%) | catalogued as rs750049177; called by muse, mutect2, varscan2
